Somatic mutation profile of tumor specimen TCGA-HT-A616-01A (aliquot TCGA-HT-A616-01A-11D-A29Q-08) from TCGA case TCGA-HT-A616, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 36.2 years (13,222 days).
Specimen TCGA-HT-A616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71d657f9-c96e-40fb-8e91-113a0861e7e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A616-10A (Blood Derived Normal), aliquot TCGA-HT-A616-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f9f3f97-233c-47f2-a1ce-09512bd1c17e

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 11, Silent 7, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD13B | c.1243T>G p.F415V | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61470758; called by muse, mutect2, varscan2
- ATRX | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 40/109 reads (37%) | catalogued as COSV64873757, COSV64875914; called by muse, mutect2, varscan2
- CAPN11 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67237330; called by muse, mutect2, varscan2
- DSG2 | c.2792G>C p.R931T | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55198836; called by muse, mutect2, varscan2
- ELAPOR1 | c.2444C>G p.T815S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV64040369; called by muse, mutect2, varscan2
- KCNA7 | c.1175T>C p.V392A | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV55502793, COSV55503326; called by muse, mutect2
- MAGEB4 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV100854628, COSV64397035; called by muse, mutect2, varscan2
- MCF2 | c.354A>T p.E118D | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as COSV58484033; called by muse, mutect2, varscan2
- RTL9 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as COSV71825525; called by muse, mutect2
- SH3D21 | c.1258G>A p.V420M (on ENST00000453908 / NM_001162530.2; = p.V309M on NM_024676.5) | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV54634124; called by muse, mutect2
- SPINT1 | c.980G>A p.R327H (on ENST00000344051 / NM_181642.3; = p.R311H on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs138167951; called by muse, mutect2, varscan2
- THBS1 | c.2644C>T p.Q882* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV52951656; called by muse, mutect2, varscan2
- ATG2B | c.3990+2_3990+3del p.X1330_splice | Splice Site (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- CCAR1 | c.1295dup p.N432Kfs*6 | Frame Shift Ins (INS) | VAF 28/88 reads (32%) | called by mutect2, varscan2
- AVPR1A | c.756G>A p.A252= | Silent (SNP) | VAF 9/227 reads (4%) | catalogued as COSV54546376; called by muse, mutect2
- CCDC54 | c.183C>T p.D61= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs144553244, COSV53757959; called by muse, mutect2, varscan2
- PRODH2 | c.1356C>A p.G452= (on ENST00000301175; = p.G376= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 13/161 reads (8%) | catalogued as COSV56559616; called by muse, mutect2
- PRR12 | c.3055C>T p.L1019= (on ENST00000615927; = p.L1840= on NM_020719.3) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV69817521; called by muse, mutect2, varscan2
- RTTN | c.5802T>G p.L1934= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV55344262; called by muse, mutect2, varscan2
- TMX2 | c.39G>A p.S13= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs751112195, COSV53554170; called by muse, mutect2, varscan2
- TTN | c.57603T>C p.Y19201= (on ENST00000591111; = p.Y11777= on NM_003319.4) | Silent (SNP) | VAF 55/121 reads (45%) | catalogued as COSV60023539; called by muse, mutect2, varscan2
